Somatic mutation profile of tumor specimen TCGA-B8-4622-01A (aliquot TCGA-B8-4622-01A-02D-1553-08) from TCGA case TCGA-B8-4622, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 57.9 years (21,135 days).
Specimen TCGA-B8-4622-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2e433cc-d7b7-4b56-99a7-d0a675e91533.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-4622-11A (Solid Tissue Normal), aliquot TCGA-B8-4622-11A-01D-1553-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33646ae9-d0f1-455b-a3b0-abf6d011caf7

The open-access MAF lists 71 somatic variants for this specimen: 52 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 36, Silent 19, Frame Shift Del 10, Nonsense Mutation 5, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.464-2A>G p.X155_splice | Splice Site (SNP) | VAF 10/38 reads (26%) | hotspot (GDC flag); catalogued as rs5030816, CS941546, CS961704, CS961705, COSV56547121, COSV56551502, COSV56558899, COSV56563919; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAC | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as COSV51759373; called by muse, mutect2, varscan2
- ATM | c.6791C>T p.T2264I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1468747245, COSV53745375; called by muse, mutect2, varscan2
- BLM | c.3420C>A p.H1140Q | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV61924176; called by muse, mutect2, varscan2
- BRCA2 | c.9889G>A p.A3297T | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66337373; called by muse, mutect2, varscan2
- CNN3 | c.185T>G p.I62R | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV64637028; called by muse, mutect2, varscan2
- COX7A2 | c.165T>G p.H55Q | Missense Mutation (SNP) | VAF 64/328 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57873944; called by muse, mutect2, varscan2
- CRYBB2 | c.12T>G p.D4E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV68005485; called by muse, mutect2
- CSMD1 | c.10181C>A p.S3394* (on ENST00000520002; = p.S3393* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV59317025; called by muse, mutect2, varscan2
- DCSTAMP | c.524T>A p.L175H | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.533); catalogued as COSV52576028, COSV52577809; called by muse, mutect2, varscan2
- FAM155A | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1216584825, COSV101027756, COSV65562634; called by muse, mutect2
- GAS2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.904); catalogued as rs752428470, COSV53407656; called by muse, mutect2, varscan2
- GCC1 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs753322522, COSV50001036; called by muse, mutect2, varscan2
- GCKR | c.1016G>C p.G339A | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV53108083; called by muse, mutect2
- GLT8D2 | c.831T>G p.F277L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV62561945; called by muse, mutect2, varscan2
- HCRTR2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.028); catalogued as rs199706844, COSV100904284, COSV63794581; called by muse, mutect2, varscan2
- IGDCC3 | c.2163C>A p.F721L | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); catalogued as rs746915008, COSV60076867, COSV60077699, COSV60079011; called by muse, mutect2, varscan2
- MAML3 | c.953A>T p.N318I | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV59074308; called by muse, mutect2, varscan2
- MECOM | c.1290G>T p.M430I (on ENST00000468789 / NM_001105078.4; = p.M618I on NM_004991.4) | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV52964690; called by muse, mutect2, varscan2
- MYBL2 | c.1897C>T p.Q633* | Nonsense Mutation (SNP) | VAF 79/422 reads (19%) | catalogued as COSV53830001; called by muse, mutect2, varscan2
- NEFH | c.919A>G p.N307D | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60217289; called by muse, mutect2, varscan2
- NUP107 | c.2753C>A p.P918Q | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57494905; called by muse, mutect2, varscan2
- NUP42 | c.925T>A p.S309T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.207); catalogued as COSV51729403, COSV51729684; called by muse, varscan2
- PCLO | c.3779A>G p.Q1260R | Missense Mutation (SNP) | VAF 84/459 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs761419864, COSV61636286; called by muse, mutect2, varscan2
- PKHD1 | c.6011C>T p.P2004L | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61876351; called by muse, mutect2, varscan2
- PRKDC | c.9458C>A p.S3153Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV58049937, COSV58052687; called by muse, mutect2, varscan2
- PSG7 | c.374T>G p.I125R | Missense Mutation (SNP) | VAF 24/456 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV68445177; called by muse, mutect2
- PTPRF | c.3221C>G p.S1074W | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63443045, COSV63445097; called by muse, mutect2, varscan2
- REC8 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 35/143 reads (24%) | catalogued as COSV61016688; called by muse, mutect2, varscan2
- RPF1 | c.979A>G p.K327E | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65705861; called by muse, mutect2, varscan2
- SETD2 | c.2121_2136del p.S708Hfs*54 | Frame Shift Del (DEL) | VAF 31/121 reads (26%) | catalogued as COSV57438093; called by mutect2, pindel, varscan2
- SLC22A11 | c.1403T>G p.L468R | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.761); catalogued as COSV57253295; called by muse, mutect2, varscan2
- SLX4IP | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV57946993; called by muse, mutect2, varscan2
- SPHKAP | c.181T>A p.L61M | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60879734; called by muse, mutect2, varscan2
- STPG4 | c.34T>C p.S12P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV54278712; called by muse, mutect2, varscan2
- TSC1 | c.617A>G p.H206R | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV53767142, COSV53774857; called by muse, mutect2, varscan2
- UGT2A3 | c.632A>C p.N211T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52360084; called by muse, mutect2, varscan2
- UTP23 | c.461C>A p.T154K | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV59124362; called by muse, mutect2
- WDFY3 | c.1136G>C p.R379T | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55701373; called by muse, mutect2, varscan2
- ZBTB3 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.193); catalogued as rs1290322485, COSV67361227; called by muse, mutect2, varscan2
- ZFHX4 | c.1959C>A p.Y653* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as COSV50830643; called by muse, mutect2, varscan2
- ZFYVE26 | c.5663G>C p.S1888T | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV61328625; called by muse, mutect2, varscan2
- ZMYM5 | c.1985A>T p.D662V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV61988505; called by muse, mutect2, varscan2
- ZNF800 | c.1730del p.P577Lfs*26 | Frame Shift Del (DEL) | VAF 66/209 reads (32%) | catalogued as COSV56174709, COSV56177823, COSV99757914; called by pindel, varscan2
- FAM13A | c.2628_2634del p.F877Rfs*3 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | called by mutect2, pindel, varscan2
- IL1RL2 | c.1578del p.K527Sfs*6 | Frame Shift Del (DEL) | VAF 43/150 reads (29%) | called by mutect2, pindel, varscan2
- LTA4H | c.629del p.L210* | Frame Shift Del (DEL) | VAF 56/143 reads (39%) | called by mutect2, pindel, varscan2
- PBRM1 | c.2926_2929del p.H976Sfs*37 (on ENST00000296302 / NM_001366071.2; = p.H976Sfs*31 on NM_018313.5) | Frame Shift Del (DEL) | VAF 58/199 reads (29%) | called by pindel, varscan2
- PDE1C | c.44_51del p.R15Hfs*15 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- SCG2 | c.852del p.S285Qfs*26 | Frame Shift Del (DEL) | VAF 69/354 reads (19%) | called by mutect2, pindel, varscan2
- THSD7B | c.1592del p.L531Wfs*36 | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | called by mutect2, pindel, varscan2
- TLE3 | c.284del p.F95Sfs*22 | Frame Shift Del (DEL) | VAF 44/194 reads (23%) | called by mutect2, pindel, varscan2
- ABCB5 | c.412A>C p.R138= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV51710039; called by muse, mutect2, varscan2
- CCNF | c.2295G>A p.V765= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs1048325887, COSV53540029; called by muse, mutect2, varscan2
- DNAH17 | c.4191C>A p.V1397= | Silent (SNP) | VAF 66/232 reads (28%) | catalogued as COSV67754713; called by muse, mutect2, varscan2
- DSG2 | c.564G>A p.E188= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs1326016998, COSV55199289; called by muse, mutect2, varscan2
- EPHA1 | c.1491A>T p.L497= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV51971433; called by muse, mutect2, varscan2
- IMMT | c.1131T>A p.T377= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV54487113; called by muse, mutect2
- IST1 | c.963C>G p.A321= (on ENST00000535424 / NM_001270976.1; = p.P307R on NM_014761.4) | Silent (SNP) | VAF 69/275 reads (25%) | catalogued as COSV58663509; called by muse, mutect2, varscan2
- KCNJ2 | c.273T>A p.A91= | Silent (SNP) | VAF 34/142 reads (24%) | catalogued as COSV54660988, COSV54661803; called by muse, mutect2, varscan2
- KDM4C | c.2250G>A p.A750= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs774249515, COSV67186639; called by muse, mutect2, varscan2
- KLF8 | c.909T>G p.P303= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV63847869; called by muse, mutect2, varscan2
- RGL1 | c.2062C>T p.L688= (on ENST00000360851 / NM_001297672.2; = p.L723= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV58985817; called by muse, mutect2, varscan2
- TCEAL5 | c.420G>T p.L140= | Silent (SNP) | VAF 80/144 reads (56%) | catalogued as COSV65503033; called by muse, mutect2, varscan2
- TDRD3 | c.1635A>G p.E545= | Silent (SNP) | VAF 51/122 reads (42%) | catalogued as COSV52156987; called by muse, mutect2, varscan2
- TMEM234 | c.195G>A p.Q65= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV59084500; called by muse, mutect2, varscan2
- TMEM69 | c.243C>A p.A81= | Silent (SNP) | VAF 94/339 reads (28%) | catalogued as COSV63432671; called by muse, mutect2, varscan2
- VAX2 | c.606G>A p.A202= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs782471705, COSV52265915; called by muse, mutect2, varscan2
- ZDBF2 | c.5028G>T p.T1676= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV65622565, COSV65626197; called by muse, mutect2, varscan2
- ZNF70 | c.1179C>T p.T393= | Silent (SNP) | VAF 47/178 reads (26%) | catalogued as COSV59532855; called by muse, mutect2, varscan2
- ZNF827 | c.247C>T p.L83= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV65227315; called by muse, mutect2, varscan2
